Somatic mutation profile of tumor specimen 0DY1QV from CCDI case PBCRWC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.6 years (3,142 days).
Specimen 0DY1QV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f5b1855-4f90-4ef9-8ae0-c5f5594d2ce4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DY1QL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dafdf58-339f-4ea1-ad70-6dd36e328dbc

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Silent 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NONO | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 156/888 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as rs749334644, COSV52139016; called by muse, mutect2, varscan2
- SNTA1 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 138/437 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs775580363; ClinVar: uncertain significance; called by muse, varscan2
- CACNA2D1 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 44/781 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.667); called by muse, mutect2
- DDX21 | c.2158G>T p.G720* | Nonsense Mutation (SNP) | VAF 166/820 reads (20%) | called by muse, mutect2, varscan2
- MAGED1 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 65/493 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- PRAMEF33 | c.288-1G>A p.X96_splice | Splice Site (SNP) | VAF 16/256 reads (6%) | called by muse, mutect2
- PRKD1 | c.1354A>G p.T452A | Missense Mutation (SNP) | VAF 121/381 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- SPOCK3 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 60/842 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- CACNA1D | c.4173G>A p.T1391= (on ENST00000350061 / NM_001128840.3; = p.T1411= on NM_000720.4) | Silent (SNP) | VAF 182/643 reads (28%) | catalogued as rs762448017; called by muse, mutect2, varscan2
- MCCC2 | c.663C>T p.A221= | Silent (SNP) | VAF 38/1206 reads (3%) | catalogued as rs978623277; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- DST | c.4297-1046A>G | Intron (SNP) | VAF 185/399 reads (46%) | called by muse, mutect2, varscan2
- FIG4 | c.1388+25T>A | Intron (SNP) | VAF 96/411 reads (23%) | called by muse, mutect2, varscan2
